CCDI case PBCUGZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/606aebb6-9514-47c7-8b86-81fff0d98440

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0DZODU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZOFA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZOFM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
